Gene-level copy-number profile of tumor specimen TCGA-68-A59J-01A from TCGA case TCGA-68-A59J, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 74.0 years (27,031 days).
Specimen TCGA-68-A59J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.f1b9f998-bed5-4f05-8173-d34e77af4e68.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-68-A59J-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/32b435d5-6f2e-4373-a48c-12bcf7409ee4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 20; copy number 1: 538; copy number 2: 22,571; copy number 3: 17,630; copy number 4: 9,400; copy number 5: 5,353; copy number 6: 2,264; copy number 7: 974; copy number 8: 332; copy number 9: 191; copy number 10: 39; copy number 13: 16; copy number 14: 189; copy number 17: 51; copy number 18: 7; copy number 19: 170; copy number 20: 8; copy number 23: 42; copy number 24: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-68-A59J-01A-21D-A26L-01): tumor purity 0.45, ploidy 2.95, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 20 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:141,167,257–141,208,376, 2 genes: RNU6-904P, RPS16P3.
- chr2:212,581,357–213,021,545, 7 genes (within-gene range 0–2): AC093865.1, LINC01878, PCED1CP, AC108066.1, MIR4776-1, MIR4776-2, AC108066.2.
- chr3:70,954,708–71,754,229, 3 genes (within-gene range 0–2): FOXP1, AC097634.4, FOXP1-AS1.
- chr14:35,538,352–35,932,325, 8 genes (within-gene range 0–2): RALGAPA1, AL137818.1, QRSL1P3, AL162311.3, NUTF2P2, BRMS1L, AL162311.1, AL162311.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 9,650 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–248,773,792, 2,596 genes, copy number 5–23 (broad region; genes not listed).
- chr2:113,970,719–114,123,293, 5 genes, copy number 8 (within-gene range 6–8): LINC01191, AC110769.1, U3, AC010982.2, AC010982.1.
- chr2:142,131,178–199,955,935, 763 genes, copy number 5–7 (within-gene range 2–7) (broad region; genes not listed).
- chr3:55,465,715–55,505,261, 3 genes, copy number 5: WNT5A, WNT5A-AS1, AC121764.1.
- chr3:100,492,619–101,163,986, 9 genes, copy number 6 (within-gene range 2–6): TMEM45A, ADGRG7, AC069223.1, GMFBP1, TFG, ABI3BP, AC080014.1, RNU6-865P, ACTR3P3.
- chr3:105,655,461–106,427,977, 4 genes, copy number 9 (within-gene range 2–9): CBLB, AC131237.1, AC079382.1, AC079382.2.
- chr3:106,515,897–106,691,320, 3 genes, copy number 9: Y_RNA, AC080097.1, Y_RNA.
- chr3:174,438,573–188,003,990, 276 genes, copy number 5–24 (within-gene range 4–24) (broad region; genes not listed).
- chr3:188,153,284–188,890,671, 1 gene, copy number 6 (within-gene range 3–6): LPP.
- chr3:188,562,238–198,222,513, 219 genes, copy number 6 (broad region; genes not listed).
- chr4:127,917,799–129,975,329, 24 genes, copy number 5: MFSD8, ABHD18, LARP1B, AC099340.1, FOSL1P1, PGRMC2, LINC02615, AC110609.1, AC078850.1, AC078850.2, JADRR, JADE1, SCLT1, AC093783.1, AC093826.1, C4orf33, CDRT15P11, ZSWIM5P3, AC105417.1, AC082650.1, AC082650.2, LINC02466, LINC02465, EEF1GP8.
- chr4:138,164,097–138,663,403, 7 genes, copy number 18 (within-gene range 1–18): SLC7A11, AC093903.1, LINC00498, LINC00499, LINC00500, AC105416.1, AC098859.1.
- chr5:58,198–45,895,970, 710 genes, copy number 7–8 (broad region; genes not listed).
- chr6:42,155,406–57,222,307, 287 genes, copy number 5–7 (broad region; genes not listed).
- chr7:70,972–57,485,895, 1,056 genes, copy number 5 (broad region; genes not listed).
- chr9:101,793,454–138,203,325, 804 genes, copy number 5 (broad region; genes not listed).
- chr11:68,754,620–70,436,584, 52 genes, copy number 10–23 (within-gene range 2–23): CPT1A, LINC02701, MRPL21, IGHMBP2, AP000808.1, MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr12:66,767–33,439,819, 834 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr14:18,333,726–24,239,242, 446 genes, copy number 6–14 (broad region; genes not listed).
- chr15:72,465,128–101,933,350, 793 genes, copy number 5 (broad region; genes not listed).
- chr17:31,709,568–34,288,334, 85 genes, copy number 6 (broad region; genes not listed).
- chr17:64,940,602–69,553,865, 101 genes, copy number 5 (broad region; genes not listed).
- chr17:69,707,193–69,707,373, 1 gene, copy number 5: AC002545.1.
- chr18:47,390–15,330,282, 376 genes, copy number 5 (broad region; genes not listed).
- chr20:57,105,741–57,601,200, 21 genes, copy number 7 (within-gene range 4–7): AL157414.2, AL157414.1, AL157414.4, AL157414.3, BMP7, BMP7-AS1, AL122058.1, Y_RNA, MIR4325, RPL39P39, SPO11, RAE1, MTND1P9, MTRNR2L3, RBM38-AS1, RBM38, AL109955.1, HMGB1P1, CTCFL, PCK1, AL035541.1.
- chr22:28,459,869–32,498,829, 174 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 538. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
